Somatic mutation profile of tumor specimen TCGA-DJ-A3V5-01A (aliquot TCGA-DJ-A3V5-01A-11D-A22Z-08) from TCGA case TCGA-DJ-A3V5, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, columnar cell; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 76.4 years (27,918 days).
Specimen TCGA-DJ-A3V5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4339095b-195e-46a6-b8b4-a2c807d145a0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DJ-A3V5-10A (Blood Derived Normal), aliquot TCGA-DJ-A3V5-10A-01D-A22Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6a718efb-894b-4391-9821-1127a71d4046

The open-access MAF lists 15 somatic variants for this specimen: 13 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 12, Silent 2, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CYP27B1 | c.575A>G p.K192R | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.56); PolyPhen benign (0.313); catalogued as COSV99141554; called by muse, mutect2
- DGKA | c.1864A>G p.I622V | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as rs944134708, COSV100092970; called by muse, mutect2, varscan2
- FANCI | c.3680G>A p.G1227E (on ENST00000310775 / NM_001376911.1; = p.G1167E on NM_018193.3) | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.009); catalogued as COSV99174698, COSV99174893; called by muse, mutect2
- FRAS1 | c.3443A>G p.N1148S | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.751); catalogued as rs775516850, COSV53665200; called by muse, mutect2, varscan2
- KERA | c.1059A>T p.*353Yext*7 | Nonstop Mutation (SNP) | VAF 3/23 reads (13%) | catalogued as COSV99899399; called by muse, mutect2
- LRRC4C | c.1177G>T p.V393F | Missense Mutation (SNP) | VAF 46/132 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.378); catalogued as COSV99537887; called by muse, mutect2, varscan2
- MEAK7 | c.98C>T p.S33L | Missense Mutation (SNP) | VAF 25/136 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.113); catalogued as rs144320129, COSV100640391; called by muse, mutect2, varscan2
- OR2B3 | c.243G>A p.M81I | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV101013779; called by muse, mutect2, varscan2
- RPGR | c.688G>A p.G230S | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.74); PolyPhen benign (0.01); catalogued as COSV58834890; called by muse, mutect2, varscan2
- RSU1 | c.148A>C p.N50H | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100590365; called by muse, mutect2, varscan2
- TIMELESS | c.2879C>T p.A960V | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.025); catalogued as rs374201861; called by muse, mutect2, varscan2
- TXNDC2 | c.958G>A p.E320K (on ENST00000306084 / NM_001098529.2; = p.E253K on NM_032243.6) | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.57); PolyPhen benign (0.07); catalogued as COSV100046026; called by muse, mutect2, varscan2
- CAMK4 | c.1083A>C p.P361= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as COSV99998898; called by muse, mutect2, varscan2
- TIMM22 | c.15C>A p.A5= | Silent (SNP) | VAF 9/20 reads (45%) | catalogued as COSV100508168; called by muse, mutect2, varscan2
